CCDI case PBCSCJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/07d642fa-bbf0-488f-b803-a573db14bb2e

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.6 years (6,442 days).

Biospecimens (2 samples)
- Sample 0DYB0L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DYB0X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
